Gene-level copy-number profile of tumor specimen ALCH-AEUV-TTP1-A from ALCHEMIST case ALCH-AEUV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.9 years (25,539 days).
Specimen ALCH-AEUV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e5373c5a-f2b9-4504-b054-b7c15062bd90.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEUV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/7dff5227-a9ec-410e-a8e2-70030126d85c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 711; copy number 2: 56,686; copy number 3: 889; copy number 4: 91; copy number 5: 9; copy number 10: 1; copy number 12: 1; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,139,287–130,190,729, 3 genes (within-gene range 0–2): CCDC74B, SMPD4, MZT2B.
- chr7:20,843,627–20,843,961, 1 gene (within-gene range 0–2): RPS26P30.
- chr16:58,083,068–58,083,168, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–522,928, 9 genes, copy number 5: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr22:21,341,595–21,371,945, 3 genes, copy number 10–14: PPP1R26P5, LINC01651, AP000552.1.

Autosomal genes at a single copy (total copy number 1): 711. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
